Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAH5, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAH5-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 9,0 cm; no invasion in rete testis; angio-invasion
unknown ;no invasion of tunica albuginea; no invasion in epididymis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD-O-3

Seminoma NOS 9061/3
Site @ Testis NOS 062.9
JAN 3/7/14

Source: NCI Genomic Data Commons file b4c23988-14c4-4c5e-b086-b5e5bf30967e (TCGA-2G-AAH5-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).